Somatic mutation profile of tumor specimen MMRF_1971_1_BM_CD138pos (aliquot MMRF_1971_1_BM_CD138pos_T1_KHS5U_L08112) from MMRF case MMRF_1971, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,123 days).
Specimen MMRF_1971_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 414388dd-4e6a-42fb-8cfe-61112bd3fed7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1971_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1971_1_PB_WBC_C2_KHS5U_L08113; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc776ac0-2a4e-4ad1-9e1c-89af31bfc89f

The open-access MAF lists 1,125 somatic variants for this specimen: 431 protein-altering or splice-affecting, 161 silent, 533 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, 3'UTR 286, Silent 161, Intron 141, 5'UTR 53, Nonsense Mutation 50, 3'Flank 19, RNA 18, 5'Flank 15, Splice Site 10, Splice Region 10, IGR 1.

Variants (750 of 1,125; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.2817G>T p.W939C | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057517310, CM119350; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.9148C>T p.Q3050* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as rs886039533, CM095980, COSV100628983; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT3 | c.342C>A p.N114K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV57754929; called by muse, mutect2, varscan2
- AKT2 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV60910964; called by muse, mutect2
- AMBP | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs1157760702; called by muse, mutect2, varscan2
- ANKRD53 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55537309; called by muse, mutect2
- APOL5 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs145777410, COSV99968497; called by muse, mutect2, varscan2
- ARHGEF33 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs1292517555, COSV67256563; called by muse, mutect2, varscan2
- ATP8B3 | c.2730C>G p.I910M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100034314; called by muse, mutect2, varscan2
- ATRX | c.3854C>A p.S1285Y | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV64876644; called by muse, mutect2
- BAHCC1 | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs782457717; called by muse, mutect2, varscan2
- BCHE | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100011955, COSV52259964; called by muse, mutect2
- BOD1L1 | c.4804G>A p.E1602K | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50006616; called by muse, mutect2, varscan2
- BRAT1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58091912; called by muse, mutect2, varscan2
- BTBD11 | c.1529G>A p.R510Q (on ENST00000280758 / NM_001018072.2; = p.R47Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV55025461; called by muse, varscan2
- C1orf198 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 182/280 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV64174727; called by muse, mutect2, varscan2
- CASZ1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs778444922; called by muse, mutect2, varscan2
- CCNL2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1249544249; called by muse, mutect2, varscan2
- CERKL | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 38/109 reads (35%) | catalogued as COSV59206470; called by muse, mutect2, varscan2
- CFAP54 | c.6877C>T p.Q2293* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs1372105608, COSV100733252; called by muse, mutect2, varscan2
- CHCHD4 | c.273C>G p.F91L (on ENST00000396914 / NM_001098502.2; = p.F104L on NM_144636.3) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs762928190; called by muse, mutect2, varscan2
- CHD6 | c.4859G>C p.R1620T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1013012745; called by muse, mutect2, varscan2
- CLTC | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.997); catalogued as COSV52244747; called by muse, mutect2, varscan2
- CNOT3 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs748449434, COSV55362405; called by muse, mutect2
- CSMD1 | c.2278G>C p.G760R (on ENST00000520002; = p.G759R on NM_033225.6) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59321052; called by muse, mutect2, varscan2
- CTSA | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs776143304; called by muse, mutect2, varscan2
- DCLRE1C | c.1360G>T p.E454* (on ENST00000378278 / NM_001350965.2; = p.E339* on NM_022487.4) | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100543038, COSV100543145; called by muse, mutect2, varscan2
- DMD | c.7810G>C p.E2604Q | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs775663860; called by muse, mutect2, varscan2
- DMTN | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV56113935; called by muse, mutect2, varscan2
- DSC1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759569406; called by muse, mutect2, varscan2
- EEF1AKNMT | c.661C>T p.Q221* (on ENST00000361735 / NM_015935.5; = p.Q135* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as rs773037113; called by muse, mutect2, varscan2
- EPHB2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.182); catalogued as rs1347733653, COSV65866476; called by muse, mutect2, varscan2
- ERLIN2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52419797, COSV99379762; called by muse, mutect2, varscan2
- FBXO38 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV57028722, COSV57029507; called by muse, mutect2, varscan2
- FCRL5 | c.967C>G p.H323D | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV62514007; called by muse, mutect2, varscan2
- FKBP14 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1369464099, COSV51653787; called by muse, varscan2
- GDF11 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs1275698336; called by muse, mutect2, varscan2
- GJA10 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs756243298; called by muse, mutect2, varscan2
- GPC2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52783645, COSV52786686, COSV99445165; called by muse, mutect2, varscan2
- GPR18 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV61621226; called by muse, mutect2
- GTPBP2 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100200067; called by muse, mutect2
- HMCN1 | c.5445G>C p.K1815N | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.489); catalogued as COSV54890865; called by muse, mutect2
- HSD17B1 | c.265+3G>A | Splice Region (SNP) | VAF 36/116 reads (31%) | catalogued as rs1295037064; called by muse, mutect2, varscan2
- IFIT2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs369628682; called by muse, mutect2, varscan2
- IGHV3-53 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 78/232 reads (34%) | catalogued as rs1390706545; called by muse, mutect2, varscan2
- ILDR2 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54830591; called by muse, mutect2
- IMPG1 | c.469-1G>A p.X157_splice | Splice Site (SNP) | VAF 42/124 reads (34%) | catalogued as rs748480710; called by muse, mutect2, varscan2
- IRF1 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as COSV55378672; called by muse, mutect2, varscan2
- ITFG1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs1381685166; called by muse, mutect2, varscan2
- ITGA2B | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs753409781, CD021198, CD061427, COSV52235917, COSV99288665; called by muse, mutect2, varscan2
- IZUMO2 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53229401, COSV53230185; called by muse, mutect2
- KCND2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV58574029, COSV58575568; called by muse, mutect2
- KCNG1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1291103932, COSV65368885; called by muse, mutect2
- KIF1C | c.3122G>T p.R1041L | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); catalogued as COSV100296971; called by muse, mutect2
- KLK5 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV60450647; called by muse, mutect2, varscan2
- KNL1 | c.3437C>T p.S1146L (on ENST00000346991 / NM_170589.5; = p.S1120L on NM_144508.5) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1409719946; called by muse, mutect2, varscan2
- LMAN2 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778202137; called by muse, mutect2, varscan2
- LNX2 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60335698; called by muse, varscan2
- LRCH4 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 36/288 reads (13%) | catalogued as COSV100052655; called by muse, mutect2, varscan2
- LRRC8C | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV64996769; called by muse, mutect2, varscan2
- LTV1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100849644; called by muse, mutect2
- LY75 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV55102793; called by muse, mutect2
- LYST | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV67709394; called by muse, mutect2
- M1AP | c.596-1G>C p.X199_splice | Splice Site (SNP) | VAF 33/130 reads (25%) | catalogued as COSV51844571; called by muse, mutect2, varscan2
- MAGED2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1200366548, COSV54497477; called by muse, mutect2, varscan2
- MAP2K5 | c.1129G>C p.D377H (on ENST00000178640 / NM_145160.3; = p.D367H on NM_002757.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV51612202; called by muse, mutect2, varscan2
- MAP3K14 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV60923886; called by muse, mutect2, varscan2
- MAPRE2 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100290305; called by muse, varscan2
- MATN4 | c.1624G>T p.E542* (on ENST00000372754; = p.E501* on NM_003833.4) | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV61353037; called by muse, mutect2, varscan2
- MAVS | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs555385198; called by muse, mutect2, varscan2
- MDN1 | c.4668G>T p.Q1556H | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs953875755; called by muse, mutect2, varscan2
- MICU1 | c.1261G>C p.D421H (on ENST00000361114 / NM_001195518.2; = p.D427H on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471814508; called by muse, varscan2
- MROH6 | c.777G>C p.R259S | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1319307220; called by muse, varscan2
- MS4A13 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs761596909; called by muse, mutect2, varscan2
- MUC16 | c.39156G>T p.K13052N | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.595); catalogued as COSV67484253; called by muse, mutect2, varscan2
- MUC16 | c.3918G>C p.E1306D | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV67453966, COSV67461092; called by muse, mutect2, varscan2
- MYH10 | c.4632G>A p.M1544I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV99344274; called by muse, mutect2, varscan2
- MYO1A | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55653995; called by muse, mutect2
- MYO5B | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs551829659, COSV99544062; called by muse, mutect2, varscan2
- NBPF4 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs1478105093; called by muse, mutect2
- NPHP3 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1341706285; called by muse, mutect2
- OAZ1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs938579865; called by muse, mutect2
- OR8H2 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs890708716; called by muse, mutect2, varscan2
- OTOG | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1360159746; called by muse, mutect2, varscan2
- PAMR1 | c.1486G>A p.E496K (on ENST00000619888 / NM_001001991.3; = p.E513K on NM_015430.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs924381135, COSV99553042; called by muse, mutect2, varscan2
- PCDHA4 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as COSV63539205; called by muse, mutect2, varscan2
- PEG3 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 160/495 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV55637885; called by muse, mutect2, varscan2
- PEX3 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100852170; called by muse, mutect2, varscan2
- PHF20L1 | c.2556G>A p.M852I | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs745635314; called by muse, varscan2
- PIGK | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.086); catalogued as COSV63062334; called by muse, mutect2, varscan2
- PLOD2 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs757386815; called by muse, mutect2, varscan2
- PLPP4 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100956470; called by muse, mutect2, varscan2
- PNMA8B | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.578); catalogued as rs771904712, COSV66536383; called by muse, varscan2
- POLR3D | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.805); catalogued as rs763785352; called by muse, mutect2, varscan2
- PPP5C | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs745727929; called by muse, mutect2, varscan2
- PRIMPOL | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV59247771; called by muse, mutect2, varscan2
- PRKCA | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1330669334; called by muse, mutect2, varscan2
- PRRC2A | c.464-8C>T | Splice Region (SNP) | VAF 25/133 reads (19%) | catalogued as rs1483357773; called by muse, mutect2, varscan2
- PTK2B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs771681042, COSV57749548; called by muse, mutect2
- PXDNL | c.3140C>G p.S1047C | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV62487184; called by muse, mutect2, varscan2
- RBM24 | c.647C>G p.A216G (on ENST00000379052 / NM_001143942.2; = p.A171G on NM_153020.2) | Missense Mutation (SNP) | VAF 137/337 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as rs1279696947; called by muse, mutect2, varscan2
- RBMS1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs758863358; called by muse, mutect2, varscan2
- RTL9 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71825467, COSV71825775; called by muse, mutect2
- RTN4RL1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs369588207; called by muse, mutect2, varscan2
- SCN11A | c.3814-1G>C p.X1272_splice | Splice Site (SNP) | VAF 20/86 reads (23%) | catalogued as COSV56571711; called by muse, mutect2
- SCN2A | c.4669C>T p.Q1557* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as rs1553463065, COSV51856899; called by muse, mutect2, varscan2
- SCN9A | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as COSV100312319; called by muse, mutect2, varscan2
- SDHAF4 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV65084982; called by muse, mutect2, varscan2
- SEC24D | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 86/206 reads (42%) | catalogued as COSV54883763; called by muse, mutect2, varscan2
- SERBP1 | c.1000C>T p.H334Y (on ENST00000370995 / NM_001018067.2; = p.H313Y on NM_015640.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867391027; called by muse, mutect2, varscan2
- SHC1 | c.1098G>A p.M366I (on ENST00000368445 / NM_183001.5; = p.M256I on NM_003029.5) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.122); catalogued as rs775299613; called by muse, mutect2, varscan2
- SLC34A2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV65941253; called by muse, mutect2, varscan2
- SLC35G6 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753542367; called by muse, mutect2, varscan2
- SLFN12L | c.1205C>T p.S402L (on ENST00000260908 / NM_001363830.1; = p.S420L on NM_001195790.1) | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs750251667, COSV99609873; called by muse, mutect2, varscan2
- SNX3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV57779220; called by muse, mutect2, varscan2
- SP140 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV59446967; called by muse, mutect2, varscan2
- SPEN | c.6199C>A p.P2067T | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV65361339; called by muse, mutect2, varscan2
- SRGAP2 | c.2878G>C p.E960Q (on ENST00000624873 / NM_001170637.4; = p.E961Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55342876; called by muse, mutect2, varscan2
- STARD10 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV58325889; called by muse, mutect2, varscan2
- STIP1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as rs759065392; called by muse, mutect2, varscan2
- STON1 | c.1667C>T p.S556L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs867655140; called by muse, mutect2, varscan2
- SYNJ1 | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.287); catalogued as rs1296959160; called by muse, mutect2, varscan2
- TADA1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1335544696; called by muse, mutect2, varscan2
- TEX13A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100782221, COSV61183333; called by muse, mutect2
- TMEM151B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs1405036924; called by muse, mutect2, varscan2
- TMEM248 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs907764591; called by muse, mutect2
- TNC | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs776487718; called by muse, mutect2, varscan2
- TNPO3 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs748952773, COSV55277919; called by muse, mutect2
- TRIP10 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99901461; called by muse, mutect2, varscan2
- TTN | c.83545G>C p.E27849Q (on ENST00000591111; = p.E20425Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | PolyPhen benign (0.295); catalogued as COSV59902451; called by muse, mutect2, varscan2
- TTN | c.31322G>C p.R10441T (on ENST00000591111; = p.R9514T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/269 reads (13%) | PolyPhen benign (0.07); catalogued as COSV100616004, COSV59870515; called by muse, mutect2, varscan2
- TUT7 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV52900154; called by muse, mutect2, varscan2
- TYR | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as CM041868, COSV54473605; called by muse, varscan2
- USH2A | c.2803C>T p.Q935* | Nonsense Mutation (SNP) | VAF 34/247 reads (14%) | catalogued as COSV56351459; called by muse, mutect2, varscan2
- USP34 | c.1254G>C p.L418F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68401468; called by muse, mutect2
- VCAN | c.9134C>T p.T3045I | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs73148633; called by muse, mutect2, varscan2
- VIPAS39 | c.632-1G>C p.X211_splice | Splice Site (SNP) | VAF 5/104 reads (5%) | catalogued as COSV58939421; called by muse, mutect2
- VSNL1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54602938; called by muse, mutect2, varscan2
- VWCE | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs927814868, COSV57112142; called by muse, mutect2, varscan2
- WDR87 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1321029007; called by muse, mutect2, varscan2
- WIF1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1194003320; called by muse, mutect2, varscan2
- ZBTB37 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as rs768160920, COSV100774492; called by muse, mutect2, varscan2
- ZMIZ2 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV54807753; called by muse, mutect2
- ZNF366 | c.2050G>C p.G684R | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV100574150; called by muse, mutect2, varscan2
- ZNF423 | c.719C>T p.S240F (on ENST00000563137 / NM_001379286.1; = p.S232F on NM_015069.4) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1031307122; called by muse, mutect2
- ZNF578 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); catalogued as rs780709400, COSV69736048, COSV69736762; called by muse, mutect2, varscan2
- ZNF592 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV55436654; called by muse, mutect2, varscan2
- ZNF682 | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs1410561453; called by muse, mutect2, varscan2
- ZNF75A | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1161274774; called by muse, mutect2
- ZP4 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1343427445; called by muse, mutect2, varscan2
- ZSCAN21 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs1562850353; called by muse, mutect2
- ABCC1 | c.4387G>C p.E1463Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ABHD11 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2
- AC005697.1 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- AC099489.1 | c.4319C>A p.A1440D | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ACVR1C | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ADAM32 | c.1234-5C>T | Splice Region (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- ADAMTS14 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS6 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ADRA2A | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALAD | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALAS1 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ALDH16A1 | c.2273C>A p.S758* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | called by muse, varscan2
- ALPK1 | c.2989G>T p.E997* | Nonsense Mutation (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- AMN | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ANKRD18A | c.2742-2A>C p.X914_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- AOAH | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAH2 | c.1648C>G p.R550G | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATP2B2 | c.1702G>A p.D568N (on ENST00000352432; = p.D534N on NM_001683.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AZU1 | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- B4GALNT4 | c.1132C>G p.R378G | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BAHCC1 | c.6950G>C p.S2317T | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL11A | c.2401G>A p.E801K (on ENST00000335712 / NM_001365609.1; = p.E835K on NM_022893.4) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- BICRA | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BICRA | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BOD1L1 | c.8891C>G p.S2964* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- BTBD17 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2
- BTBD2 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1orf21 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- C2orf16 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- C5AR2 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- C8orf31 | n.439-3C>A | Splice Region (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CASP8AP2 | c.3967C>A p.L1323I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CBL | c.2566C>G p.Q856E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CC2D1B | c.70-1G>C p.X24_splice | Splice Site (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- CCDC144A | c.4120G>C p.D1374H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2
- CCDC197 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CCDC93 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CCM2 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CCNO | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CDHR3 | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDK8 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 39/59 reads (66%) | called by muse, mutect2, varscan2
- CELSR3 | c.6571G>C p.D2191H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CENPE | c.5035G>T p.E1679* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- CENPF | c.6701C>T p.S2234F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CEP250 | c.3837G>C p.E1279D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CEP295 | c.3814C>T p.H1272Y | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- CFAP251 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CHRM5 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILP | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CLCN2 | c.2141C>A p.T714K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLMN | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.022); called by muse, mutect2
- CMYA5 | c.2996C>G p.S999C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL14A1 | c.1818C>G p.I606M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL27A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPSF2 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 9/278 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CRIM1 | c.2397G>C p.L799F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRTAM | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CSDE1 | c.2152G>C p.E718Q (on ENST00000358528 / NM_001007553.3; = p.E687Q on NM_007158.6) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CSDE1 | c.2080G>C p.D694H (on ENST00000358528 / NM_001007553.3; = p.D663H on NM_007158.6) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, varscan2
- CSMD2 | c.9264C>A p.Y3088* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CUBN | c.10550G>T p.G3517V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CUBN | c.10258G>T p.D3420Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP27A1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DAPK1 | c.2541G>C p.E847D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- DCLRE1C | c.1750G>C p.E584Q (on ENST00000378278 / NM_001350965.2; = p.E469Q on NM_022487.4) | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DDX25 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- DEPDC5 | c.1841G>A p.R614K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, varscan2
- DGKA | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKG | c.1762-3C>T | Splice Region (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- DHX15 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- DIPK1A | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DKK1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- DMRTC1 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH10 | c.1816-1G>C p.X606_splice (on ENST00000409039; = p.X545_splice on NM_207437.3) | Splice Site (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- DNTTIP2 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK9 | c.2914C>T p.Q972* (on ENST00000376460 / NM_001366676.2; = p.Q973* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- DSCAML1 | c.4489G>A p.E1497K (on ENST00000321322; = p.E1437K on NM_020693.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- E2F3 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGF | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ELAVL3 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ERMARD | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- ETS2 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- EYA4 | c.1774G>C p.E592Q (on ENST00000531901 / NM_001301013.1; = p.E586Q on NM_004100.5) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- FAT4 | c.13647G>C p.K4549N | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCRLB | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FKBP7 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FREM3 | c.4752G>C p.K1584N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FRMD4A | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GATM | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GGNBP2 | c.642-6C>T | Splice Region (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- GLB1L2 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- GPR149 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GREB1L | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); called by muse, mutect2
- HCN1 | c.849+5G>A | Splice Region (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2
- HEATR1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD2 | c.2014C>G p.L672V | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECTD4 | c.4736T>C p.V1579A | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HELZ | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HIVEP1 | c.4631C>G p.S1544C | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- HLA-DQA2 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- HS2ST1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR6 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTT | c.1406C>A p.S469* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- IARS1 | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 37/117 reads (32%) | called by muse, mutect2, varscan2
- IFNA13 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- INPPL1 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ITIH5 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KAZALD1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- KCNA6 | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNG3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- KLF14 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KLF2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLHL14 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- L1TD1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- LAS1L | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- LBHD1 | c.352G>A p.D118N (on ENST00000431002 / NM_001367940.1; = p.D92N on NM_024099.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); called by muse, varscan2
- LIMD1 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- LRATD2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRCH2 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LRFN4 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRIF1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRP6 | c.4029G>C p.K1343N | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.094); called by muse, varscan2
- LRRC14 | c.1412C>G p.S471* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- LRRC32 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC4 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.04); called by muse, mutect2
- LRRC4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2
- LRRK1 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- LRRTM3 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2
- MAK | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MALRD1 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- MAN1A2 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MAN2B2 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- MAN2C1 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K14 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPT | c.1291G>A p.E431K (on ENST00000262410 / NM_001377265.1; = p.E356K on NM_016835.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MARCHF11 | c.549G>C p.L183F | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARCKS | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MBD3 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBIP | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MCFD2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MET | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MIA3 | c.5231C>G p.S1744C | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MID1 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); called by muse, mutect2
- MRPL47 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC16 | c.34457A>T p.E11486V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC5AC | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.26); called by muse, mutect2, varscan2
- MX2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); called by muse, mutect2
- MXRA5 | c.8098G>A p.E2700K | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- MYH10 | c.2770C>G p.L924V | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.081); called by muse, mutect2
- MYLK | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2
- MYMK | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NCOA3 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDNF | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- NDUFAF6 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- NDUFV3 | c.232G>A p.D78N (on ENST00000340344 / NM_001001503.2; = p.D443N on NM_021075.4) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEMF | c.1857G>A p.Q619= | Splice Region (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- NFAT5 | c.3102G>C p.Q1034H | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NHSL1 | c.3608C>T p.P1203L | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NID2 | c.4118-7C>G | Splice Region (SNP) | VAF 9/249 reads (4%) | called by muse, mutect2
- NOS3 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- NRXN2 | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.087); called by muse, varscan2
- NUP58 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NVL | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NXN | c.74C>G p.S25W | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- OGA | c.1944G>C p.K648N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OPLAH | c.3194C>G p.S1065C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR13C2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR2Z1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2
- OTUD4 | c.1260-1G>A p.X420_splice (on ENST00000447906 / NM_001366057.1; = p.X355_splice on NM_001102653.1) | Splice Site (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- OTUD7A | c.2016C>G p.F672L (on ENST00000307050 / NM_001382637.1; = p.F665L on NM_130901.3) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- OVCH1 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PABPN1 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PALM3 | c.1283G>A p.G428E (on ENST00000340790; = p.G443E on NM_001145028.2) | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- PARP11 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PHF2 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKG1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); called by muse, mutect2
- PLEKHG3 | c.2251G>A p.E751K (on ENST00000394691; = p.E807K on NM_001308147.2) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POLR2B | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.411); called by muse, mutect2
- POU2AF1 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPARGC1A | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- PPEF1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PPIL6 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PPP2R2B | c.235G>C p.E79Q (on ENST00000394409; = p.E145Q on NM_181674.2) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PPP4R3C | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRKACA | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCG | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PRPF8 | c.3679C>T p.Q1227* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- PRRC2B | c.3507G>C p.L1169F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PSMB1 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN3 | c.1530G>C p.L510F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RABGGTB | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI1 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RBM20 | c.3106G>C p.D1036H | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- RBMS3 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELN | c.7046C>G p.S2349C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- REV3L | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RGS16 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- RIF1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RNF103 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- RNF111 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- RNF213 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | called by muse, varscan2
- RNF39 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RPL23A | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- RSF1 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RTKN | c.300G>C p.K100N (on ENST00000272430 / NM_001015055.2; = p.K87N on NM_033046.2) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SAMHD1 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SAMHD1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCG3 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCUBE2 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SELENOV | c.964-1G>C p.X322_splice | Splice Site (SNP) | VAF 50/173 reads (29%) | called by muse, mutect2, varscan2
- SEMA6C | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 152/275 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SESN3 | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SF3B1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SFPQ | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- SGO2 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH2D2A | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SLC24A2 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SLCO1B3 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SNCAIP | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SNX4 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- SOGA1 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SORCS2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- SPAG17 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.298); called by muse, mutect2
- SPDYE3 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SPOCK3 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SPTA1 | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTB | c.-50G>T | Splice Region (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SSC5D | c.3995C>A p.S1332* | Nonsense Mutation (SNP) | VAF 108/416 reads (26%) | called by muse, mutect2, varscan2
- ST7L | c.1575G>C p.M525I | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- STAC | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- STIM2 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- STK31 | c.1987C>G p.Q663E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SVIL | c.2845G>A p.E949K (on ENST00000355867 / NM_021738.3; = p.E523K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); called by muse, mutect2
- SYNE2 | c.17186A>G p.Q5729R | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D31 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D9 | c.1586C>G p.S529* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TENT5C | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM184B | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TMEM59L | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMTC3 | c.2473G>C p.E825Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TOMM70 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRANK1 | c.6862A>T p.S2288C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TRBV7-4 | c.185C>G p.S62* | Nonsense Mutation (SNP) | VAF 56/161 reads (35%) | called by muse, mutect2, varscan2
- TRIM23 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- TRPC4 | c.-27-1G>C | Splice Site (SNP) | VAF 74/147 reads (50%) | called by muse, mutect2, varscan2
- TTC14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 135/328 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TTC3 | c.2168C>G p.S723C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.23191G>C p.E7731Q (on ENST00000591111; = p.E6804Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TUBGCP2 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUT7 | c.2920C>G p.L974V | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2
- UBP1 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- UBR1 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- URB2 | c.1998C>A p.F666L | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.057); called by muse, mutect2
- USP15 | c.2071G>C p.E691Q (on ENST00000280377 / NM_001351159.2; = p.E662Q on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- USP7 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VILL | c.1484G>C p.R495T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- VNN1 | c.1490G>C p.R497T | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WAS | c.132G>C p.L44F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.326); called by muse, mutect2
- WDR11 | c.2492G>C p.R831T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); called by muse, mutect2
- WDR64 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- WFS1 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZAN | c.3389C>T p.S1130F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZBTB32 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZFHX2 | c.4504G>A p.V1502I | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ZFHX4 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ZNF286A | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF469 | c.4982G>A p.G1661E (on ENST00000437464; = p.G1689E on NM_001367624.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ZNF501 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 15/477 reads (3%) | called by muse, mutect2
- ZNF646 | c.2414C>G p.S805C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ZNF676 | c.236C>T p.S79F (on ENST00000650058; = p.S47F on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZNF749 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- ZNF75D | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF836 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.154); called by muse, mutect2
- ZSCAN16 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- ZXDB | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.082); called by mutect2, varscan2
- AC073610.2 | c.567C>T p.S189= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as rs1463736920; called by muse, mutect2, varscan2
- ADAMTS14 | c.2298C>G p.L766= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV64599679; called by muse, mutect2, varscan2
- ADAMTS16 | c.894C>T p.V298= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs768862940; called by muse, mutect2, varscan2
- ADAMTS19 | c.1533C>T p.I511= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as rs1045876693; called by muse, varscan2
- ADGRF5 | c.1005C>A p.L335= | Silent (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3237C>T p.F1079= (on ENST00000370717 / NM_001366005.1; = p.F1066= on NM_012302.4) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV54664065; called by muse, mutect2, varscan2
- ALLC | c.498C>A p.L166= | Silent (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- ANK1 | c.3654G>T p.R1218= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- ANO3 | c.2622G>C p.L874= | Silent (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- ANO8 | c.1422G>T p.L474= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- APOB | c.12291G>C p.L4097= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2
- APOB | c.3015G>A p.L1005= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ASTN1 | c.1713G>T p.V571= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV99922572; called by muse, mutect2, varscan2
- ATP2B3 | c.1728C>T p.F576= | Silent (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- ATP8B1 | c.639C>T p.L213= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs139511564; called by muse, mutect2, varscan2
- AUP1 | c.162C>T p.C54= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs778434732; called by muse, mutect2, varscan2
- BRDT | c.1560G>C p.L520= | Silent (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- BSN | c.1539G>C p.L513= | Silent (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- BSPRY | c.750G>A p.K250= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as rs1362297819; called by muse, mutect2
- BTBD11 | c.732C>T p.L244= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CACNA1A | c.3063G>A p.A1021= | Silent (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- CACNA1S | c.5499G>C p.L1833= | Silent (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- CACNB1 | c.1689G>A p.R563= | Silent (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- CAMK1G | c.726C>T p.F242= | Silent (SNP) | VAF 83/130 reads (64%) | catalogued as COSV50523432; called by muse, mutect2, varscan2
- CASS4 | c.1722G>A p.K574= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV64385649; called by muse, mutect2, varscan2
- CDH15 | c.1551C>T p.F517= | Silent (SNP) | VAF 33/44 reads (75%) | called by muse, mutect2, varscan2
- CEACAM18 | c.696G>A p.L232= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1050C>A p.L350= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- CHRNA3 | c.849G>A p.L283= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- CHST10 | c.1017C>T p.F339= | Silent (SNP) | VAF 103/362 reads (28%) | catalogued as rs552990765, COSV51804180; called by muse, mutect2, varscan2
- CLUH | c.867C>T p.I289= (on ENST00000435359; = p.I327= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV70929927; called by muse, mutect2, varscan2
- CMYA5 | c.6882C>T p.I2294= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV71404891; called by muse, mutect2, varscan2
- COL6A3 | c.663G>A p.V221= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- CTSS | c.90C>G p.L30= | Silent (SNP) | VAF 73/358 reads (20%) | called by muse, mutect2, varscan2
- DACH1 | c.756G>A p.R252= | Silent (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- DDX27 | c.1840C>T p.L614= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- DIP2C | c.1257G>A p.R419= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as rs1412081240; called by muse, mutect2, varscan2
- DNAH11 | c.12930G>A p.L4310= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- DOCK6 | c.297C>T p.I99= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV53924813; called by muse, mutect2, varscan2
- EPYC | c.760C>T p.L254= | Silent (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- EXOG | c.51G>A p.L17= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- FASTKD5 | c.1320G>A p.L440= | Silent (SNP) | VAF 45/165 reads (27%) | called by muse, mutect2, varscan2
- FBXL7 | c.204G>A p.Q68= | Silent (SNP) | VAF 78/273 reads (29%) | called by muse, mutect2, varscan2
- FBXO47 | c.192C>T p.I64= | Silent (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- FCGR2C | c.204G>C p.L68= | Silent (SNP) | VAF 99/176 reads (56%) | called by muse, mutect2, varscan2
- FCRL4 | c.363G>C p.L121= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1480142208; called by muse, mutect2
- FGF8 | c.192C>T p.L64= (on ENST00000344255 / NM_033164.4; = p.L46= on NM_006119.6) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1002998549, COSV60142842; called by muse, mutect2, varscan2
- FIGLA | c.138C>G p.L46= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- FIGN | c.1473C>T p.L491= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs565838605; called by muse, mutect2
- FLNC | c.4434G>A p.Q1478= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- FOXB2 | c.216C>T p.I72= | Silent (SNP) | VAF 7/169 reads (4%) | called by muse, mutect2
- FREM2 | c.249C>T p.F83= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99746735; called by muse, mutect2
- GEMIN5 | c.2232G>A p.K744= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV53563282; called by muse, mutect2, varscan2
- GLI2 | c.1200C>G p.L400= (on ENST00000361492 / NM_001374353.1; = p.L417= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- GPR4 | c.321C>T p.F107= | Silent (SNP) | VAF 82/213 reads (38%) | called by muse, mutect2, varscan2
- GPRC5A | c.217C>T p.L73= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- GSAP | c.2334G>T p.R778= | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- H2BC11 | c.72G>A p.K24= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs764127288, COSV60363046; called by muse, mutect2, varscan2
- HCCS | c.735C>T p.V245= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- HEPACAM | c.213G>A p.L71= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- HK1 | c.1437C>T p.L479= | Silent (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- HMCES | c.42C>T p.L14= | Silent (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- HTR7 | c.324C>T p.F108= | Silent (SNP) | VAF 72/136 reads (53%) | called by muse, mutect2, varscan2
- IFNA2 | c.121C>T p.L41= | Silent (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- IGBP1 | c.228G>C p.L76= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60556186; called by muse, mutect2, varscan2
- IGHJ6 | c.57C>G p.S19= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs181338437; called by muse, varscan2
- IGHV1-69D | c.348G>C p.A116= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.105G>A p.Q35= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as rs570640149; called by muse, mutect2, varscan2
- INSR | c.1155C>T p.L385= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs1040724024, COSV57168990; called by muse, mutect2, varscan2
- IQCN | c.3132C>T p.V1044= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- IQCN | c.630C>T p.L210= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- JAG2 | c.2457C>T p.F819= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs587755609; called by muse, mutect2, varscan2
- KAT6B | c.1302C>T p.L434= | Silent (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- KCNV1 | c.36G>A p.P12= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- KIAA1217 | c.4200G>T p.V1400= | Silent (SNP) | VAF 72/214 reads (34%) | catalogued as rs776818509; called by muse, mutect2, varscan2
- KIAA1217 | c.5781G>A p.Q1927= | Silent (SNP) | VAF 20/751 reads (3%) | catalogued as COSV100287484; called by muse, mutect2
- KIAA1755 | c.405T>G p.P135= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- KIF13A | c.2895C>T p.I965= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- KIF26B | c.6114G>T p.L2038= | Silent (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- KIF5B | c.120G>A p.V40= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- LRRC73 | c.345C>A p.L115= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV104389629; called by muse, mutect2, varscan2
- LY9 | c.234C>T p.V78= | Silent (SNP) | VAF 107/612 reads (17%) | catalogued as rs142988998; called by muse, mutect2, varscan2
- LYPD6 | c.39G>C p.L13= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- MAST2 | c.1437G>A p.L479= | Silent (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- MC1R | c.42C>T p.L14= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- MED1 | c.720C>A p.I240= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs754448367; called by muse, mutect2, varscan2
- MEX3A | c.1539G>A p.T513= | Silent (SNP) | VAF 34/214 reads (16%) | catalogued as rs1558100702, COSV101348972; called by muse, mutect2, varscan2
- MICALL2 | c.1536G>A p.S512= | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as rs760914141, COSV99876019; called by muse, mutect2, varscan2
- MMRN1 | c.351C>T p.L117= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV53337085; called by muse, mutect2, varscan2
- MRPL34 | c.165G>A p.P55= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- MSH3 | c.213C>T p.F71= | Silent (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- NAT2 | c.57G>A p.L19= | Silent (SNP) | VAF 49/239 reads (21%) | catalogued as COSV54061222; called by muse, mutect2, varscan2
- NIN | c.4278G>A p.Q1426= | Silent (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- NLRP12 | c.2766C>T p.I922= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- NUP210 | c.654C>G p.L218= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- OBSL1 | c.759G>A p.K253= | Silent (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- OR13C2 | c.187C>T p.L63= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- OR1B1 | c.894C>G p.L298= | Silent (SNP) | VAF 85/245 reads (35%) | called by muse, mutect2, varscan2
- OR2L3 | c.888G>A p.V296= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as rs907812243, COSV63455117; called by muse, mutect2, varscan2
- OR5T2 | c.234C>T p.L78= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs775999147, COSV100506854; called by muse, mutect2, varscan2
- OSMR | c.2142C>T p.I714= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- PCNT | c.5058G>A p.Q1686= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs145665841; called by muse, mutect2, varscan2
- PCNX4 | c.1704C>T p.L568= (on ENST00000406854 / NM_001330177.2; = p.L334= on NM_022495.5) | Silent (SNP) | VAF 75/202 reads (37%) | called by muse, mutect2, varscan2
- PDXP | c.423G>A p.P141= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- PFKM | c.1119G>C p.L373= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9555G>C p.L3185= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV101005078; called by muse, mutect2, varscan2
- PKN2 | c.207G>C p.L69= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- PKNOX2 | c.831C>A p.L277= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV53549528; called by muse, mutect2, varscan2
- PLA2R1 | c.4215G>A p.L1405= | Silent (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- PLEC | c.7140C>G p.L2380= (on ENST00000322810 / NM_201380.4; = p.L2270= on NM_000445.5) | Silent (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2142G>A p.A714= (on ENST00000414982 / NM_001166111.2; = p.A666= on NM_006702.5) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs769646919; called by mutect2, varscan2
- POMGNT2 | c.1545G>A p.L515= | Silent (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- POPDC3 | c.123C>T p.F41= | Silent (SNP) | VAF 75/241 reads (31%) | catalogued as COSV54646442, COSV99633620; called by muse, mutect2, varscan2
- PPP1R7 | c.291G>A p.L97= | Silent (SNP) | VAF 5/132 reads (4%) | called by muse, mutect2
- PRKCD | c.1626C>T p.L542= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs782746660, COSV100387793; called by muse, mutect2
- PTGR2 | c.915G>A p.Q305= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- PTPN1 | c.1233C>G p.V411= | Silent (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- RAB20 | c.90C>T p.F30= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57439607; called by muse, mutect2
- RALGAPB | c.4377G>C p.R1459= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- RBM5 | c.1953C>T p.L651= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1379806199; called by muse, mutect2, varscan2
- REG4 | c.456C>T p.F152= | Silent (SNP) | VAF 121/309 reads (39%) | called by muse, mutect2, varscan2
- RFC2 | c.90C>T p.S30= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs1157276554; called by muse, mutect2, varscan2
- RPL23A | c.9G>A p.P3= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs1337583092; called by muse, mutect2, varscan2
- RYR2 | c.6085C>T p.L2029= | Silent (SNP) | VAF 18/102 reads (18%) | called by mutect2, varscan2
- SCN2A | c.48C>T p.F16= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as COSV99329979; called by muse, mutect2, varscan2
- SKAP2 | c.150G>A p.K50= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SLC12A5 | c.2187C>A p.I729= (on ENST00000454036 / NM_001134771.2; = p.I706= on NM_020708.5) | Silent (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- SLC15A2 | c.153G>A p.V51= | Silent (SNP) | VAF 165/424 reads (39%) | called by muse, mutect2, varscan2
- SLC35E2B | c.486C>G p.V162= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- SLC37A1 | c.1242C>T p.V414= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- SLC39A7 | c.1320G>T p.L440= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1032G>A p.S344= | Silent (SNP) | VAF 87/268 reads (32%) | catalogued as rs758648041, COSV54226720, COSV54229582; called by muse, mutect2, varscan2
- SNX17 | c.903C>T p.L301= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- SOWAHA | c.129C>G p.L43= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1461762323; called by muse, mutect2, varscan2
- SOX4 | c.165G>A p.P55= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1471703351; called by muse, mutect2, varscan2
- SRRT | c.2259C>T p.F753= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1396217434; called by muse, mutect2, varscan2
- ST8SIA2 | c.1005C>G p.L335= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs762341121; called by muse, mutect2, varscan2
- STC2 | c.486C>T p.F162= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- SYN2 | c.639C>T p.I213= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs774609915; called by muse, varscan2
- SYP | c.30G>A p.V10= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- TAGAP | c.243G>A p.L81= | Silent (SNP) | VAF 31/40 reads (78%) | called by muse, mutect2, varscan2
- TMEM178B | c.840G>A p.R280= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs1196845417, COSV73803110; called by muse, mutect2, varscan2
- TMEM220 | c.216G>A p.V72= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- TMEM269 | c.363C>T p.I121= (on ENST00000536543; = p.I79= on NM_001354602.1) | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- TNFSF13B | c.99G>A p.R33= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TRHR | c.966C>T p.L322= | Silent (SNP) | VAF 89/244 reads (36%) | catalogued as rs267601709, COSV100305111, COSV61234161; called by muse, mutect2, varscan2
- TRIM47 | c.1224C>G p.L408= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as rs753164056; called by muse, varscan2
- TSPAN3 | c.48C>G p.L16= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- TTC22 | c.1464G>C p.L488= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- TTC23L | c.789G>A p.Q263= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV72205907, COSV72205981; called by muse, mutect2
- TTI2 | c.225C>T p.L75= | Silent (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- TTPAL | c.105G>T p.L35= | Silent (SNP) | VAF 55/205 reads (27%) | called by muse, mutect2, varscan2
- VPS41 | c.1794G>A p.L598= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- WSCD2 | c.834C>T p.T278= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs367855700, COSV54590449; called by muse, mutect2, varscan2
- WWC2 | c.3468C>T p.L1156= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as COSV67862050; called by muse, mutect2
- ZBTB10 | c.367C>T p.L123= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as rs1435026459; called by muse, mutect2, varscan2
- ZCCHC2 | c.876C>T p.R292= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs1425242081; called by muse, varscan2
- ZFP91 | c.1146G>A p.K382= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ZNF418 | c.483C>T p.F161= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs1475281583; called by muse, mutect2, varscan2
- ZNF7 | c.1284G>A p.L428= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ZNF827 | c.396C>G p.L132= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ABCC9 | c.406+1442G>T | Intron (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- ABCD2 | c.*3300G>A | 3'UTR (SNP) | VAF 5/93 reads (5%) | catalogued as rs1463698776; called by muse, mutect2
- ABL2 | c.*4558G>A | 3'UTR (SNP) | VAF 14/86 reads (16%) | catalogued as rs78206228; called by mutect2, varscan2
- AC064805.2 | n.1928C>A | RNA (SNP) | VAF 9/48 reads (19%) | catalogued as COSV61193796; called by muse, mutect2, varscan2
- AC083899.1 | n.651C>T | RNA (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6223G>T | Intron (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- AC124067.4 | n.6C>G | RNA (SNP) | VAF 20/40 reads (50%) | catalogued as rs1288809952; called by muse, mutect2, varscan2
- ADAMTS1 | c.-56G>C | 5'UTR (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53172407, COSV99536346; called by muse, mutect2
- ADAMTS13 | c.-19C>T | 5'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs782227169, COSV100746907; called by muse, mutect2, varscan2
- ADAMTS14 | c.*244C>T | 3'UTR (SNP) | VAF 25/74 reads (34%) | catalogued as rs751873228; called by muse, mutect2, varscan2
- ADCY7 | c.*1225G>A | 3'UTR (SNP) | VAF 37/51 reads (73%) | called by muse, mutect2, varscan2
- ADGRA2 | c.*357C>T | 3'UTR (SNP) | VAF 12/186 reads (6%) | catalogued as rs373708632; called by muse, mutect2
- ADRA1A | c.-71C>T | 5'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99372674; called by muse, mutect2, varscan2
- AEBP1 | c.254-325G>A | Intron (SNP) | VAF 103/293 reads (35%) | called by muse, mutect2, varscan2
- AFDN | chr6:167970842 C>G | 3'Flank (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- AGMO | c.*38G>T | 3'UTR (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- AGRN | c.3389-36G>A | Intron (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- AK4 | c.*519G>C | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- AKAP10 | c.*1755C>G | 3'UTR (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- AL137028.1 | n.58G>T | RNA (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- ALDH16A1 | c.2248-84C>T | Intron (SNP) | VAF 18/95 reads (19%) | called by muse, varscan2
- ALDH1L1 | c.1983-385C>A | Intron (SNP) | VAF 73/230 reads (32%) | called by muse, varscan2
- ALG9 | c.566-44G>A | Intron (SNP) | VAF 11/24 reads (46%) | catalogued as rs782126858; called by muse, mutect2, varscan2
- ALK | c.*196G>A | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- ALX4 | c.*1844G>A | 3'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- ANK2 | chr4:113383816 G>C | 3'Flank (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1354-300C>G | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- ANKS1A | c.*1814G>C | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ANXA4 | c.*625C>G | 3'UTR (SNP) | VAF 12/66 reads (18%) | catalogued as rs763366309; called by muse, mutect2, varscan2
- AOPEP | c.*207C>G | 3'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- AP1G2 | c.-449G>A | 5'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- AP2M1 | c.1174-263A>G | Intron (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- APCDD1L | c.*304G>A | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- APOL4 | c.44+207C>T | Intron (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100113150; called by muse, mutect2, varscan2
- APOL4 | c.-19-23C>G | Intron (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- APOOP5 | n.400A>G | RNA (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.*2887C>T | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.39+586C>T | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1212092222; called by muse, mutect2, varscan2
- ARIH2 | c.*708C>A | 3'UTR (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- ARL4C | c.*93G>A | 3'UTR (SNP) | VAF 75/208 reads (36%) | called by muse, mutect2, varscan2
- ARMC8 | c.1134+116G>A | Intron (SNP) | VAF 89/259 reads (34%) | catalogued as COSV61768162; called by muse, mutect2, varscan2
- ATOX1 | c.*47-959G>A | Intron (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- ATP2B4 | c.*2153G>C | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- ATP5MC3 | c.*1463G>C | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*4233C>T | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*419G>C | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- B4GALT5 | c.*1000G>A | 3'UTR (SNP) | VAF 27/89 reads (30%) | catalogued as rs544520590; called by muse, mutect2, varscan2
- BATF3 | c.91-55G>A | Intron (SNP) | VAF 40/196 reads (20%) | called by muse, mutect2
- BCL2 | c.*5271G>C | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- BCL2L12 | c.360-35C>G | Intron (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- BCL9L | c.-301G>A | 5'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- BCLAF1P1 | n.884C>G | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- BIRC3 | c.-1382A>G | 5'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- BMP3 | c.*2748C>G | 3'UTR (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- BMP6 | c.*366C>T | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- BPTF | chr17:67825516 G>A | 5'Flank (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- BRAF | c.*596G>C | 3'UTR (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- BRAF | c.*137G>C | 3'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- BRWD3 | c.*1035G>C | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- BTBD8 | c.-163C>T | 5'UTR (SNP) | VAF 55/164 reads (34%) | called by muse, mutect2, varscan2
- BTBD9 | c.*6445G>A | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- BZW1 | c.-11+253G>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- C15orf40 | chr15:82988666 C>G | 3'Flank (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- C1orf109 | c.*532C>G | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- C1orf116 | c.*176G>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- C1orf21 | c.190-22259G>C | Intron (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- C1orf21 | c.*1112C>T | 3'UTR (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- CA14 | c.*397G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- CACNG8 | c.*6065G>A | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- CACUL1 | c.886+1397C>G | Intron (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- CAMK2N1 | c.-644C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- CAMK4 | c.*7206G>C | 3'UTR (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- CAPN3 | c.2263+90G>C | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- CAPS2 | c.1670-1395C>T | Intron (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- CAST | c.75+648C>T | Intron (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- CAVIN4 | c.*319C>G | 3'UTR (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2
- CCDC13 | c.825+79G>C | Intron (SNP) | VAF 3/19 reads (16%) | catalogued as rs1440301252; called by muse, mutect2
- CCDC13 | c.720+94G>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs1559654164; called by muse, mutect2
- CCDC183 | c.439-13C>T | Intron (SNP) | VAF 28/71 reads (39%) | catalogued as rs775161270; called by muse, mutect2, varscan2
- CCDC39 | chr3:180679618 G>A | 5'Flank (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CCDC6 | c.*3240C>G | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+1251C>T | Intron (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CCDC85C | c.793+23098G>A | Intron (SNP) | VAF 84/248 reads (34%) | called by muse, mutect2, varscan2
- CCM2L | c.1403-10C>G | Intron (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- CCNJL | c.-39G>A | 5'UTR (SNP) | VAF 23/85 reads (27%) | catalogued as rs371701963; called by muse, mutect2, varscan2
- CCNT2 | c.*908G>A | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- CCT8L2 | c.*63G>T | 3'UTR (SNP) | VAF 76/140 reads (54%) | called by mutect2, varscan2
- CD2BP2 | c.*1520G>C | 3'UTR (SNP) | VAF 72/185 reads (39%) | called by muse, mutect2, varscan2
- CD2BP2 | c.*1367G>A | 3'UTR (SNP) | VAF 58/167 reads (35%) | called by muse, mutect2, varscan2
- CD81 | c.*260G>A | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CD96 | c.*353G>A | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- CDC37L1 | c.-178G>A | 5'UTR (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- CDC73 | c.*1244C>T | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- CDH12 | c.*558C>G | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- CDH3 | c.2281-79C>G | Intron (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- CDK3 | c.*32G>C | 3'UTR (SNP) | VAF 40/116 reads (34%) | catalogued as rs546544216, COSV100044685; called by muse, mutect2, varscan2
- CDK6 | c.*5358C>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- CDON | c.1198+90G>C | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CELSR1 | c.9036-119C>T | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- CFP | c.1244+155G>C | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CHCHD2 | c.*2G>T | 3'UTR (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.351G>A | RNA (SNP) | VAF 21/96 reads (22%) | catalogued as rs776945093; called by muse, mutect2, varscan2
- CHD3 | c.*858C>G | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- CHRNB2 | c.*3804C>T | 3'UTR (SNP) | VAF 42/286 reads (15%) | called by muse, varscan2
- CKAP2L | c.-5G>C | 5'UTR (SNP) | VAF 78/188 reads (41%) | called by muse, mutect2, varscan2
- CKB | c.*172G>T | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- CLEC1B | c.439-136C>G | Intron (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- CNOT3 | c.259-121G>A | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CNOT7 | c.*1211G>C | 3'UTR (SNP) | VAF 37/91 reads (41%) | catalogued as rs1407168450; called by muse, mutect2, varscan2
- CNTN2 | c.3014-189G>A | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as rs1197087761; called by muse, mutect2
- COL22A1 | c.1758+51C>G | Intron (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- COL9A1 | c.*722G>A | 3'UTR (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- CP | c.2555-28C>G | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, varscan2
- CRELD1 | c.-252G>A | 5'UTR (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- CRIP1 | c.-646G>A | 5'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- CSAD | c.567+40C>G | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.*1613G>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, varscan2
- CSRNP3 | c.*125A>G | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CTBP2 | c.*2535T>A | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- CTBP2 | c.*686G>A | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- CTIF | c.*1126C>T | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CTIF | c.*1932C>T | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- CTSS | c.*891G>C | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- CTSS | c.*763G>C | 3'UTR (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- CTSV | c.*285C>G | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- CUX1 | c.*6624C>T | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- CUX1 | c.*8320C>G | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- CUX1 | c.*8771C>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CXADR | c.*3225G>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009793 G>C | 3'Flank (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- CYRIB | c.*118C>G | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- DAO | chr12:108879889 C>T | 5'Flank (SNP) | VAF 48/165 reads (29%) | called by muse, varscan2
- DBNL | c.*2203G>A | 3'UTR (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.2653-375G>A | Intron (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- DDX20 | c.*607C>G | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- DEFA5 | c.*40C>G | 3'UTR (SNP) | VAF 123/381 reads (32%) | called by muse, mutect2, varscan2
- DENND3 | c.384-59G>A | Intron (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99371695; called by muse, mutect2, varscan2
- DLG4 | c.*421G>T | 3'UTR (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- DLX1 | c.513+102C>T | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- DLX1 | c.*1349C>G | 3'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100543271; called by muse, mutect2, varscan2
- DNAH17 | c.7992+109G>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- DST | chr6:56458306 C>G | 3'Flank (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- DTNA | c.*2790G>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs944216135; called by muse, mutect2, varscan2
- DUSP15 | c.426+1029C>T | Intron (SNP) | VAF 3/19 reads (16%) | catalogued as COSV54067085; called by muse, mutect2
- DYNLL1 | c.133-128C>T | Intron (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- DYNLRB2 | c.80-89C>T | Intron (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- EFHC2 | c.*838C>T | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- EIF3E | c.471+1752C>T | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as COSV55202328; called by muse, mutect2
- EIF5A2 | c.*298A>T | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691779 C>T | 3'Flank (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- EML2 | c.49+65G>A | Intron (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- ENG | c.*101G>A | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- EPB41 | c.*2568G>C | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- EPB41L3 | c.*7-56G>C | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- ERI2 | c.*685C>G | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- ESYT2 | chr7:158732156 G>A | 3'Flank (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ETFA | c.816+65G>A | Intron (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- ETV3 | c.*3619C>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
375 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 375 other) are not listed here.
